Somatic mutation profile of tumor specimen TCGA-QM-A5NM-01A (aliquot TCGA-QM-A5NM-01A-11D-A28R-08) from TCGA case TCGA-QM-A5NM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 67.8 years (24,781 days).
Specimen TCGA-QM-A5NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76c545ca-afab-4d7a-ac87-cfe68e00f85b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QM-A5NM-10A (Blood Derived Normal), aliquot TCGA-QM-A5NM-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e78c5f3b-3f70-48a3-8ff5-68740c071188

The open-access MAF lists 55 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 9, In Frame Del 1, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 55/115 reads (48%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 35/37 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519982, CM107067, COSV52660956, COSV52677021, COSV52760397, COSV52839973; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ANKRD13A | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs748435968, COSV55677971; called by muse, mutect2, varscan2
- CALHM5 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs1363970144; called by muse, mutect2, varscan2
- CORIN | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs368765606; called by muse, mutect2, varscan2
- DHX9 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.222); catalogued as COSV62359992; called by muse, mutect2, varscan2
- DOCK2 | c.2783G>A p.R928Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs754028409, COSV56961008; called by muse, mutect2, varscan2
- EBF2 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV68779997; called by muse, mutect2, varscan2
- FBN3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs755074368, COSV99559759; called by muse, mutect2, varscan2
- FGD6 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59691290; called by muse, mutect2, varscan2
- HIP1 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs138838220, COSV61183378; called by muse, mutect2, varscan2
- IL5RA | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1195236737, COSV56525108; called by muse, mutect2, varscan2
- JUP | c.1801C>G p.Q601E | Missense Mutation (SNP) | VAF 41/41 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV100159760; called by muse, mutect2, varscan2
- MGAM | c.4528C>T p.R1510C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760873437; called by muse, mutect2
- PLEKHA6 | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55334099; called by muse, mutect2, varscan2
- PPP2R1A | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV100436084; called by muse, mutect2, varscan2
- PRPF8 | c.4780T>C p.C1594R | Missense Mutation (SNP) | VAF 402/430 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100517817; called by muse, mutect2, varscan2
- SBF1 | c.3370A>G p.R1124G | Missense Mutation (SNP) | VAF 55/60 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748976030; called by muse, mutect2, varscan2
- SIX4 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); catalogued as rs796487039, COSV99382581; called by muse, mutect2, varscan2
- SOGA3 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107575; called by muse, mutect2, varscan2
- ARFGEF3 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCOR | c.1481G>A p.C494Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1A | c.2780G>A p.G927D | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRM2 | c.200G>C p.C67S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); called by muse, mutect2
- CNTN2 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- FAT2 | c.7212T>G p.I2404M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- FKBP3 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, varscan2
- FLNA | c.3920C>A p.T1307N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FSD2 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- GOLGA7 | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- KDM2A | c.40T>C p.L14= | Splice Region (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- KRTAP10-8 | c.520A>C p.I174L | Missense Mutation (SNP) | VAF 179/425 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP2 | c.2191A>G p.I731V | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MARCHF2 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MC3R | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 92/114 reads (81%) | SIFT tolerated (0.18); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MEOX2 | c.293C>G p.S98C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NID2 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIK3R1 | c.1322_1360del p.N441_N453del (on ENST00000521381 / NM_181523.3; = p.N171_N183del on NM_181504.4) | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel
- PLK1 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTEN | c.932del p.N311Mfs*6 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- REPIN1 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RIN2 | c.1409C>A p.P470Q (on ENST00000255006 / NM_001242581.1; = p.P421Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNCAIP | c.944A>C p.Y315S | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS15 | c.848A>T p.Y283F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- XPO6 | c.2420G>C p.R807P | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- CEP72 | c.1305C>T p.G435= | Silent (SNP) | VAF 13/125 reads (10%) | catalogued as rs376000627; called by muse, mutect2, varscan2
- CHST8 | c.612T>C p.N204= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as rs770122076; called by muse, mutect2, varscan2
- GALNT8 | c.1155C>T p.N385= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs370114403; called by muse, mutect2, varscan2
- INTS10 | c.897T>C p.D299= | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as rs761855373; called by muse, mutect2, varscan2
- KRBA1 | c.306C>T p.P102= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs887479451, COSV55445005; called by muse, mutect2, varscan2
- MAB21L2 | c.375G>A p.A125= | Silent (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- OR5D18 | c.786G>T p.V262= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV61738721; called by muse, mutect2, varscan2
- SERPINB7 | c.123G>T p.L41= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- TGM6 | c.441G>T p.L147= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824720 G>A | 5'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
